Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-7065, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-7065-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Consultation Report

* Addended *

SPECIMEN(S) RECEIVED

- 1. Oral-Cavity: RT. tongue resection, short anterior, long superior
- 2. Oral Cavity: Rt. posterior margin
- 3. Oral Cavity: Floor of mouth mucosa margin
- 4. Oral Cavity: medial margin superior
- 5. Oral Cavity: Anterior margin
- 6. Oral Cavity: Floor of mouth deep margin
- 7. Oral Cavity: deep tongue muscle
- 8. Neck: level I A neck
- 9. Neck: bilateral neck contents
- 10. Neck: Rt. sublingual gland
- 11. Surgical Waste
- 12. Neck: left neck level 4 node

DIAGNOSIS

- 1. Right tongue resection:
Squamous cell carcinoma, moderately differentiated.
- 2. The maximum dimension of the tumour is 2.7 cm.
- 3. The maximum thickness of the tumour is 1.2 cm.
- 4. No perineural or lymphovascular invasion is identified.
- 5. All margins are free of tumour (> 0.5 cm).
- 6. Right posterior margin:
Negative for malignancy.
- 7. Floor of mouth mucosa margin:
Negative for malignancy.
- 8. Medial margin superior:
Negative for malignancy.
- 9. Anterior margin:
Negative for malignancy.

[page 2 of 5]
6. Floor of mouth deep margin:

- Negative for malignancy.

7. Deep tongue muscle:

- Negative for malignancy.

8. Neck; level IA:

- Fat and fibrous tissue, negative for malignancy.

9. Bilateral neck contents:

- Bilateral submandibular glands with mild chronic inflammation, negative for malignancy.

- Thirty-nine lymph nodes, negative for malignancy (0/39).

10. Right sublingual gland:

- Sublingual gland with chronic inflammation, negative for malignancy.

11. Surgical waste:

- Soft tissue with no diagnostic abnormalities (examined grossly).

12. Left neck; level IV:

- One lymph node, negative for malignancy (0/1).

SYNOPTIC DATA

Specimen Type: Resection: Right tongue resection.

Tumor Site: Tongue

Histologic Type: Squamous cell carcinoma, conventional

Tumor Size: Greatest dimension: 2.7 cm

Tumor thickness: 1.2 cm

Histologic Grade: G2: Moderately differentiated

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent

Perineural Invasion: Absent

Pathologic Staging (pTNM): pT2: Tumor of lip or oral cavity more than 2 cm but not more than 4 cm in greatest dimension

pN0: No regional lymph node metastasis
for aerodigestive sites

Number of regional lymph nodes
examined: 40

Number of regional lymph nodes
involved: 0

pMX: Distant metastasis cannot be assessed

ELECTRONICALLY VERIFIED BY

GROSS DESCRIPTION

[page 3 of 5]
1. The specimen is labeled the patient's name and as "Oral Cavity: Right tongue resection, short anterior, long superior". It consists of a portion of right tongue measuring 3.5 cm SI x 1.8 cm ML x 4.8 cm AP cm. There are two sutures orientation. There is an ill-defined ulcerated tumor involving the lateral surface of the tongue. The tumor measures 2.2 SI x 1.2 ML x 2.7 AP cm. The tumor is ill-defined, solid in consistency, ulcerated on the surface with a gray-tan color. It is located at 0.8 cm from the superior margin, 0.7 cm from the medial margin, 0.8 cm from the deep margin, 0.8 cm from the anterior margin, and 1.2 from the posterior margin. The deep margin is submitted for intraoperative consultation. Representative sections are submitted.

1A- frozen section block resubmitted. (Deep margin (perpendicular))

1B- anterior margin

1C- inferior margin

1D- posterior margin

1E- superior margin

1F-1H - tumor with deep margin.

1I- normal tongue.

Two pieces of tumor and one piece of normal were taken for tissue bank.

2. The specimen labeled with the patient's name and as "Oral Cavity: Right posterior margin- consists of a fragment of tissue that measures 2.2 x 0.5 x 0.2 cm. The specimen is frozen for intraoperative consultation.

2A- frozen section block resubmitted.

3. The specimen labeled with the patient's name and as "Oral Cavity: Floor of mouth mucosa margin consists of a fragment of tissue that measures 0.9 x 0.7 x 0.4 cm. The specimen is frozen for intraoperative consultation.

3A- frozen section block resubmitted.

4. The specimen labeled with the patient's name and as "Oral Cavity: Medial margin superior" consists of a fragment of tissue that measures 2.2 x 0.4 x 0.3 cm. The specimen is frozen for intraoperative consultation.

4A- frozen section block resubmitted.

5. The specimen labeled with the patient's name and as "Oral Cavity: Anterior margin" consists of a fragment of tissue that measures 1.6 x 0.3 x 0.2 cm. The specimen is frozen for intraoperative consultation.

5A- frozen section block resubmitted.

6. The specimen labeled with the patient's name and as "Oral Cavity: Floor of mouth deep margin" consists of a fragment of tissue that measures 0.8 x 0.4 x 0.3 cm. The specimen is frozen for intraoperative consultation.

6A- frozen section block resubmitted.

7. The specimen labeled with the patient's name and as "Oral Cavity: Deep tongue muscle" consists of two fragments of tissue that measures 0.7 x 0.5 x 0.4 cm and 0.8 x 0.4 x 0.3 cm. The specimen is frozen for intraoperative

[page 4 of 5]
consultation.

7A- frozen section block resubmitted.

8. The specimen container is labeled with the patient's name and as "Neck: Level IA neck". It consists of a fragment of tissue measuring 1.3 x 0.5 x 0.5 cm.

8A- specimen in toto.

9. The specimen labeled with the patient's name and as "Neck: Bilateral neck contents" consists of an oriented standard right and left neck dissection with overall dimensions of 18.0 x 9.5 x 2.2 cm. There is a diagram indicating levels I-IV on the right and levels I-IV on the left. The right submandibular gland measures 4.5 x 2.8 x 1.4 cm while the left submandibular gland measures 4.0 x 2.8 x 1.2 cm and are both unremarkable. Multiple lymph nodes ranging from 0.5 to 1.8 cm are identified in multiple levels. Representative sections are submitted.

9A- right submandibular gland

9B- multiple lymph nodes level I right

9C- 9D- one lymph node serially sectioned level II right

9E-one lymph node bisected level II right

9F-9G-multiple lymph nodes each level II right

9H-one lymph node bisected level III right

9I-multiple lymph nodes level IV right

9J-one lymph node bisected level IV right

9K-left submandibular gland

9L-soft tissue level I left

9M- 9N- one possible lymph node each bisected level II left

9O-one lymph node bisected level III left

9P-multiple lymph nodes level III left

9Q-one lymph node bisected level III left

9R-multiple lymph nodes level III left

9S-one lymph node bisected level IV left

9T-multiple lymph nodes level IV left.

10. The specimen container is labeled with the patient's name and as "Neck: Right sublingual gland". It consists of a sublingual gland measuring 2.7 x 2.5 x 1.4 cm and is unremarkable.

10A- representative sections submitted.

11. The specimen container is labeled with the patient's name and as "Surgical Waste". It consists of a piece of unoriented dark brown soft tissue measuring 2.0 x 1.5 x 1.3 cm. No gross abnormalities are noted. No sections are submitted.

12. The specimen container is labeled with the patient's name and as "Neck: Left neck level IV node". It consists of a fragment of tissue measuring 0.8 x

[page 5 of 5]
0.5 x 0.4 cm.

12A- specimen in toto.

QUICK SECTION

1A. Deep margin: negative for carcinoma

2A. Right posterior margin: negative for carcinoma

3A. Floor of mouth mucosal margin: negative for carcinoma

4A. Medial margin superior: negative for carcinoma

5A. Anterior margin: negative for carcinoma

6A. Floor of mouth deep margin: negative for carcinoma

7A. Deep tongue muscle: negative for carcinoma

Reported to

Addendum Comment

A p16 has been performed and is negative in the tumour cells.

Source: NCI Genomic Data Commons file 72eb2aea-110e-4424-b34e-5129f22ecc02 (TCGA-CQ-7065.B7C1D9AF-5974-4C31-80F6-BD15AD8D1DF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).